Somatic mutation profile of tumor specimen C3L-06430-07 (aliquot CPT0393390009) from CPTAC case C3L-06430, project CPTAC-3 (Skin — Nevi and Melanomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIC; Age at diagnosis: 67.1 years (24,514 days).
Specimen C3L-06430-07: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Head & Neck; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 710638b5-5d90-42aa-ad5e-6eb2d833c79d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-06430-31 (Blood Derived Normal), aliquot CPT0390730003; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b992e190-83f0-4f92-8652-ee58315f87f8

The open-access MAF lists 328 somatic variants for this specimen: 211 protein-altering or splice-affecting, 109 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 187, Silent 109, Nonsense Mutation 14, Intron 8, Splice Region 5, Splice Site 4, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 554/978 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- ABCB5 | c.2936C>T p.S979F (on ENST00000404938 / NM_001163941.2; = p.S534F on NM_178559.6) | Missense Mutation (SNP) | VAF 195/653 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs866901072, COSV51721769; called by muse, mutect2, varscan2
- ABCF1 | c.958G>A p.V320I (on ENST00000326195 / NM_001025091.2; = p.V282I on NM_001090.3) | Missense Mutation (SNP) | VAF 110/739 reads (15%) | SIFT tolerated (0.17); PolyPhen benign (0.015); catalogued as rs548473493, COSV100400760; called by muse, mutect2, varscan2
- ACSM2A | c.1679G>A p.R560Q (on ENST00000219054; = p.R481Q on NM_001308169.2) | Missense Mutation (SNP) | VAF 133/491 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs148142047; called by muse, mutect2, varscan2
- AHNAK2 | c.3809G>A p.G1270D | Missense Mutation (SNP) | VAF 186/666 reads (28%) | SIFT tolerated (0.39); PolyPhen benign (0.191); catalogued as rs1328958004; called by muse, mutect2, varscan2
- APOBEC3B | c.70G>A p.E24K | Missense Mutation (SNP) | VAF 164/487 reads (34%) | SIFT tolerated (0.8); PolyPhen benign (0.133); catalogued as rs1457291230; called by muse, mutect2, varscan2
- ARHGEF12 | c.1141C>T p.R381C | Missense Mutation (SNP) | VAF 58/262 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1565484109; called by muse, mutect2, varscan2
- BABAM2 | c.721C>T p.P241S | Missense Mutation (SNP) | VAF 157/316 reads (50%) | SIFT tolerated (0.39); PolyPhen probably damaging (0.992); catalogued as COSV59629688; called by muse, mutect2, varscan2
- C12orf54 | c.166G>A p.E56K | Missense Mutation (SNP) | VAF 102/304 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV58360921; called by muse, mutect2, varscan2
- CACNA1B | c.6401G>A p.G2134E | Missense Mutation (SNP) | VAF 311/521 reads (60%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.959); catalogued as rs199777163, COSV53122394; called by muse, mutect2, varscan2
- CCDC158 | c.1571C>T p.S524F | Missense Mutation (SNP) | VAF 75/519 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); catalogued as rs545357328; called by muse, mutect2, varscan2
- CDC5L | c.191C>T p.S64F | Missense Mutation (SNP) | VAF 64/484 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs915033150, COSV65176602; called by muse, mutect2, varscan2
- CFAP54 | c.7115C>T p.S2372F | Missense Mutation (SNP) | VAF 117/412 reads (28%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.697); catalogued as rs894088687, COSV61570780; called by muse, mutect2, varscan2
- CLCA2 | c.2665C>T p.P889S | Missense Mutation (SNP) | VAF 94/459 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as rs1229792964, COSV100991300; called by muse, mutect2, varscan2
- CNGB3 | c.413G>A p.R138K | Missense Mutation (SNP) | VAF 309/730 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.013); catalogued as rs1563749108; called by muse, mutect2, varscan2
- COL21A1 | c.1823G>A p.G608E | Missense Mutation (SNP) | VAF 42/345 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV55161063; called by muse, mutect2, varscan2
- CPZ | c.1147G>A p.D383N (on ENST00000360986 / NM_001014447.3; = p.D372N on NM_003652.3) | Missense Mutation (SNP) | VAF 73/478 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs748182777, COSV59924014; called by muse, mutect2, varscan2
- CSHL1 | c.91C>T p.P31S | Missense Mutation (SNP) | VAF 203/772 reads (26%) | SIFT tolerated (0.14); PolyPhen probably damaging (1); catalogued as COSV51990117; called by muse, mutect2, varscan2
- CXCR6 | c.887G>A p.R296Q | Missense Mutation (SNP) | VAF 215/502 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.116); catalogued as rs141955108; called by muse, mutect2, varscan2
- DOCK3 | c.3964G>A p.E1322K | Missense Mutation (SNP) | VAF 84/334 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1320625824; called by muse, mutect2, varscan2
- DSCAM | c.4750G>A p.E1584K | Missense Mutation (SNP) | VAF 141/496 reads (28%) | SIFT tolerated (0.4); PolyPhen benign (0.028); catalogued as rs758792903, COSV68021636; called by muse, mutect2, varscan2
- DSCAM | c.1294G>A p.G432R | Missense Mutation (SNP) | VAF 191/706 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101261234; called by muse, mutect2, varscan2
- EDEM3 | c.280G>A p.G94S | Missense Mutation (SNP) | VAF 133/394 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs146347520; called by muse, mutect2, varscan2
- EMILIN2 | c.258-1G>A p.X86_splice | Splice Site (SNP) | VAF 31/213 reads (15%) | catalogued as rs1473555257; called by muse, mutect2, varscan2
- ENAM | c.1828G>A p.E610K | Missense Mutation (SNP) | VAF 62/449 reads (14%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.948); catalogued as COSV68536827; called by muse, mutect2, varscan2
- EPHB6 | c.506C>T p.S169F | Missense Mutation (SNP) | VAF 448/1767 reads (25%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.683); catalogued as rs779876904; called by muse, varscan2
- ERI2 | c.616A>G p.I206V | Missense Mutation (SNP) | VAF 83/326 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.389); catalogued as COSV55501987; called by muse, mutect2, varscan2
- ERN1 | c.1831C>T p.R611C | Missense Mutation (SNP) | VAF 227/513 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs745516592; called by muse, mutect2, varscan2
- FAAH2 | c.379C>T p.P127S | Missense Mutation (SNP) | VAF 169/237 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66506696; called by muse, mutect2, varscan2
- FAM47C | c.653G>A p.G218E | Missense Mutation (SNP) | VAF 315/466 reads (68%) | SIFT tolerated (0.08); PolyPhen benign (0.373); catalogued as rs782385927; called by muse, mutect2, varscan2
- FBXO31 | c.1330C>T p.Q444* | Nonsense Mutation (SNP) | VAF 187/587 reads (32%) | catalogued as COSV61151343; called by muse, mutect2, varscan2
- FGF12 | c.587C>T p.S196L (on ENST00000454309 / NM_021032.5; = p.S134L on NM_004113.6) | Missense Mutation (SNP) | VAF 112/401 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.678); catalogued as COSV53169240; called by muse, mutect2, varscan2
- FLNC | c.7252G>A p.E2418K | Missense Mutation (SNP) | VAF 249/654 reads (38%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.85); catalogued as COSV57950219; called by muse, mutect2, varscan2
- GDF3 | c.269G>A p.G90D | Missense Mutation (SNP) | VAF 77/199 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs753885780, COSV100325379; called by muse, mutect2, varscan2
- GLIPR1 | c.358G>A p.E120K | Missense Mutation (SNP) | VAF 156/393 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs574219796, COSV56990729; called by muse, mutect2, varscan2
- GOLGA8T | c.779C>T p.S260L | Missense Mutation (SNP) | VAF 32/269 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as rs1399204381; called by muse, mutect2, varscan2
- HMGB4 | c.214C>T p.Q72* | Nonsense Mutation (SNP) | VAF 214/524 reads (41%) | catalogued as COSV53940723; called by muse, mutect2, varscan2
- HTR3A | c.1111C>A p.Q371K | Missense Mutation (SNP) | VAF 22/342 reads (6%) | SIFT tolerated (0.43); PolyPhen benign (0.102); catalogued as COSV100248244; called by muse, mutect2
- HYDIN | c.12876C>T p.I4292= | Splice Region (SNP) | VAF 33/123 reads (27%) | catalogued as rs1473703305; called by muse, mutect2, varscan2
- KCNH5 | c.2746G>A p.E916K | Missense Mutation (SNP) | VAF 54/449 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.777); catalogued as rs372872099; called by muse, mutect2, varscan2
- KCNJ15 | c.280G>A p.D94N | Missense Mutation (SNP) | VAF 132/651 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs147233830; called by muse, mutect2, varscan2
- LITAF | c.446C>T p.P149L | Missense Mutation (SNP) | VAF 188/369 reads (51%) | SIFT deleterious (0.03); PolyPhen benign (0.206); catalogued as rs1422804373; called by muse, mutect2, varscan2
- LMLN | c.188C>T p.P63L | Missense Mutation (SNP) | VAF 143/377 reads (38%) | SIFT tolerated (0.08); PolyPhen benign (0.123); catalogued as rs781075916, COSV54560167; called by muse, mutect2, varscan2
- LRRC4C | c.1883G>A p.R628Q | Missense Mutation (SNP) | VAF 63/262 reads (24%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0.003); catalogued as rs778525061, COSV53417840; called by muse, mutect2, varscan2
- LRRC53 | c.208G>A p.E70K | Missense Mutation (SNP) | VAF 80/399 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs890624231; called by muse, mutect2, varscan2
- MAS1 | c.767C>T p.S256L | Missense Mutation (SNP) | VAF 141/328 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.196); catalogued as rs373119084; called by muse, mutect2, varscan2
- MGAM2 | c.3337G>A p.D1113N | Missense Mutation (SNP) | VAF 721/1079 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs777073088, COSV72176088; called by muse, mutect2, varscan2
- MGAM2 | c.5315G>A p.R1772Q | Missense Mutation (SNP) | VAF 265/1361 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs751007006; called by muse, mutect2, varscan2
- MME | c.1841A>G p.N614S | Missense Mutation (SNP) | VAF 132/467 reads (28%) | SIFT tolerated (0.18); PolyPhen benign (0.019); catalogued as rs771747158; called by muse, mutect2, varscan2
- MOGAT2 | c.892G>A p.E298K | Missense Mutation (SNP) | VAF 154/365 reads (42%) | SIFT tolerated (0.33); PolyPhen benign (0.007); catalogued as COSV52219974; called by muse, mutect2, varscan2
- MUC12 | c.12346G>A p.G4116S (on ENST00000379442; = p.G3973S on NM_001164462.1) | Missense Mutation (SNP) | VAF 303/3978 reads (8%) | SIFT tolerated (0.34); catalogued as rs1235588963; called by muse, mutect2
- MUC16 | c.29887C>T p.P9963S | Missense Mutation (SNP) | VAF 58/387 reads (15%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.148); catalogued as COSV67478182; called by muse, mutect2, varscan2
- MYO15B | c.7243G>A p.D2415N | Missense Mutation (SNP) | VAF 169/375 reads (45%) | SIFT tolerated (0.08); PolyPhen benign (0.388); catalogued as rs951598042; called by muse, mutect2, varscan2
- NELL1 | c.1516C>T p.P506S | Missense Mutation (SNP) | VAF 137/302 reads (45%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.854); catalogued as COSV54292798; called by muse, mutect2, varscan2
- NLRP2 | c.29A>G p.N10S | Missense Mutation (SNP) | VAF 262/588 reads (45%) | SIFT tolerated (0.07); PolyPhen benign (0.437); catalogued as rs765131798; called by muse, mutect2, varscan2
- OR2J1 | c.658G>A p.G220S | Missense Mutation (SNP) | VAF 372/711 reads (52%) | SIFT tolerated (0.11); PolyPhen benign (0.112); catalogued as rs774058683; called by muse, mutect2, varscan2
- OR4S2 | c.4G>A p.E2K | Missense Mutation (SNP) | VAF 84/136 reads (62%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV56746238; called by muse, mutect2, varscan2
- OSBPL5 | c.1066G>A p.E356K | Missense Mutation (SNP) | VAF 43/252 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.195); catalogued as rs146107856; called by muse, mutect2, varscan2
- OTUD4 | c.830C>T p.S277F (on ENST00000447906 / NM_001366057.1; = p.S212F on NM_001102653.1) | Missense Mutation (SNP) | VAF 34/306 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99031040; called by muse, mutect2, varscan2
- PCDHB11 | c.373G>A p.D125N | Missense Mutation (SNP) | VAF 189/341 reads (55%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV53377380; called by muse, mutect2, varscan2
- PCDHB9 | c.409G>A p.E137K | Missense Mutation (SNP) | VAF 230/387 reads (59%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.139); catalogued as COSV53378001; called by muse, mutect2, varscan2
- PCDHGA4 | c.727C>T p.L243F | Missense Mutation (SNP) | VAF 194/358 reads (54%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV54002972; called by muse, mutect2, varscan2
- PCOLCE2 | c.625C>T p.R209* | Nonsense Mutation (SNP) | VAF 206/487 reads (42%) | catalogued as rs758681084; called by muse, mutect2, varscan2
- PDE10A | c.1294C>T p.R432C | Missense Mutation (SNP) | VAF 43/263 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1463619240; called by muse, mutect2, varscan2
- PDGFRA | c.2287G>A p.D763N | Missense Mutation (SNP) | VAF 174/327 reads (53%) | SIFT tolerated (0.19); PolyPhen benign (0.33); catalogued as COSV57276093; called by muse, mutect2, varscan2
- PHF3 | c.445C>T p.R149C | Missense Mutation (SNP) | VAF 136/347 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1236548188; called by muse, mutect2, varscan2
- PIP5K1A | c.1082C>T p.S361F (on ENST00000368888 / NM_001135638.2; = p.S348F on NM_003557.3) | Missense Mutation (SNP) | VAF 218/513 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV62958197, COSV62958457; called by muse, mutect2, varscan2
- PODXL2 | c.510G>T p.E170D | Missense Mutation (SNP) | VAF 231/624 reads (37%) | SIFT tolerated (0.2); PolyPhen benign (0.222); catalogued as COSV61065184; called by muse, mutect2, varscan2
- PRPS1L1 | c.184G>A p.E62K | Missense Mutation (SNP) | VAF 237/744 reads (32%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.646); catalogued as rs751865681, COSV72649817; called by muse, mutect2, varscan2
- PTK6 | c.610G>A p.E204K | Missense Mutation (SNP) | VAF 233/720 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.987); catalogued as COSV99420675; called by muse, mutect2, varscan2
- RASGRP3 | c.1181C>T p.T394M (on ENST00000402538 / NM_001349975.2; = p.T393M on NM_015376.2 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 186/404 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.847); catalogued as rs370150483; called by muse, mutect2, varscan2
- REG3G | c.79G>A p.E27K | Missense Mutation (SNP) | VAF 189/368 reads (51%) | SIFT tolerated (0.06); PolyPhen benign (0.028); catalogued as COSV55452543, COSV99709375; called by muse, mutect2, varscan2
- ROBO4 | c.2722C>T p.R908W | Missense Mutation (SNP) | VAF 219/534 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.53); catalogued as rs377333725, COSV100127772; called by muse, mutect2
- SAMSN1 | c.499C>T p.R167C | Missense Mutation (SNP) | VAF 166/565 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs368727307; called by muse, mutect2, varscan2
- SCARA5 | c.709G>A p.D237N | Missense Mutation (SNP) | VAF 327/763 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1300476303, COSV57282126; called by muse, mutect2, varscan2
- SDK2 | c.538C>T p.R180C | Missense Mutation (SNP) | VAF 162/677 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.935); catalogued as rs545696462, COSV66198814; called by muse, mutect2, varscan2
- SLC14A1 | c.126G>A p.M42I | Missense Mutation (SNP) | VAF 134/304 reads (44%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.918); catalogued as COSV100424871, COSV58932024; called by muse, mutect2, varscan2
- SLC27A5 | c.1192G>A p.D398N | Missense Mutation (SNP) | VAF 74/363 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54020077; called by muse, mutect2, varscan2
- SLCO1B3 | c.1778C>T p.A593V | Missense Mutation (SNP) | VAF 55/291 reads (19%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.789); catalogued as COSV53933260; called by muse, mutect2, varscan2
- SLIT2 | c.796C>T p.P266S | Missense Mutation (SNP) | VAF 50/333 reads (15%) | SIFT tolerated (0.4); PolyPhen benign (0.001); catalogued as COSV56586880, COSV99882828; called by muse, varscan2
- SLIT2 | c.800C>T p.S267F | Missense Mutation (SNP) | VAF 184/344 reads (53%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.61); catalogued as COSV99888072; called by muse, varscan2
- SRRM2 | c.3514C>T p.P1172S | Missense Mutation (SNP) | VAF 103/534 reads (19%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0); catalogued as rs757842082; called by muse, mutect2, varscan2
- STK31 | c.2705G>A p.G902E | Missense Mutation (SNP) | VAF 208/469 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1345152620, COSV100669857; called by muse, mutect2, varscan2
- STXBP5L | c.1319G>A p.G440E | Missense Mutation (SNP) | VAF 72/254 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1272368617; called by muse, mutect2, varscan2
- TANGO6 | c.764C>T p.S255F | Missense Mutation (SNP) | VAF 208/471 reads (44%) | SIFT tolerated (0.1); PolyPhen benign (0.365); catalogued as rs1029906567; called by muse, mutect2, varscan2
- TPTE | c.1138G>A p.E380K (on ENST00000618007 / NM_199261.4; = p.E362K on NM_199259.4) | Missense Mutation (SNP) | VAF 97/526 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.046); catalogued as rs781489069; called by muse, varscan2
- TRPV5 | c.1781G>C p.R594T | Missense Mutation (SNP) | VAF 96/971 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54687171; called by muse, mutect2, varscan2
- TTLL7 | c.1345C>T p.R449* | Nonsense Mutation (SNP) | VAF 100/252 reads (40%) | catalogued as COSV53088638; called by muse, mutect2, varscan2
- UBR3 | c.4903A>G p.I1635V | Missense Mutation (SNP) | VAF 28/316 reads (9%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as rs754763909; called by muse, mutect2
- UNC80 | c.1357C>T p.R453* | Nonsense Mutation (SNP) | VAF 62/379 reads (16%) | catalogued as COSV55889397; called by muse, mutect2, varscan2
- USP9X | c.2248C>T p.R750* | Nonsense Mutation (SNP) | VAF 62/279 reads (22%) | catalogued as COSV61066040; called by muse, mutect2, varscan2
- VCAN | c.5209A>G p.T1737A | Missense Mutation (SNP) | VAF 40/412 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.01); catalogued as rs750926890; called by muse, mutect2
- VPS72 | c.623C>T p.P208L | Missense Mutation (SNP) | VAF 81/544 reads (15%) | SIFT tolerated (0.3); PolyPhen benign (0.006); catalogued as rs907898877; called by muse, mutect2, varscan2
- VWDE | c.2254C>T p.R752W | Missense Mutation (SNP) | VAF 159/686 reads (23%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.971); catalogued as rs375633029; called by muse, mutect2, varscan2
- ZIM3 | c.1363G>A p.A455T | Missense Mutation (SNP) | VAF 72/449 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.387); catalogued as rs141519115, COSV99517472; called by muse, mutect2, varscan2
- ZNF729 | c.3238G>T p.E1080* | Nonsense Mutation (SNP) | VAF 119/382 reads (31%) | catalogued as rs1323194689; called by muse, mutect2, varscan2
- ZNF99 | c.1198G>A p.E400K | Missense Mutation (SNP) | VAF 52/380 reads (14%) | SIFT tolerated (0.56); PolyPhen probably damaging (0.996); catalogued as COSV68054861; called by muse, mutect2, varscan2
- ABCA4 | c.6477C>T p.S2159= | Splice Region (SNP) | VAF 154/352 reads (44%) | called by muse, mutect2, varscan2
- AC018709.1 | c.169G>A p.G57R | Missense Mutation (SNP) | VAF 50/426 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- ACSL3 | c.304A>G p.K102E | Missense Mutation (SNP) | VAF 26/398 reads (7%) | SIFT tolerated (0.12); PolyPhen benign (0.066); called by muse, mutect2
- ADGRD1 | c.1216A>T p.S406C | Missense Mutation (SNP) | VAF 57/519 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.726); called by muse, mutect2, varscan2
- ANO3 | c.2269G>A p.E757K | Missense Mutation (SNP) | VAF 106/242 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2
- ANO3 | c.2271A>C p.E757D | Missense Mutation (SNP) | VAF 102/232 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2
- ATP13A5 | c.366A>C p.L122F | Missense Mutation (SNP) | VAF 130/408 reads (32%) | SIFT tolerated (0.11); PolyPhen benign (0.392); called by muse, mutect2, varscan2
- BACE2 | c.619C>G p.P207A | Missense Mutation (SNP) | VAF 74/330 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- BHLHA9 | c.560G>A p.R187Q | Missense Mutation (SNP) | VAF 191/535 reads (36%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.795); called by muse, mutect2, varscan2
- CACNA1B | c.6400G>A p.G2134R | Missense Mutation (SNP) | VAF 312/526 reads (59%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- CATSPERB | c.1684G>A p.E562K | Missense Mutation (SNP) | VAF 138/482 reads (29%) | SIFT tolerated (0.83); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- CATSPERB | c.1334A>G p.N445S | Missense Mutation (SNP) | VAF 85/334 reads (25%) | SIFT tolerated (0.17); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- CCIN | c.1091G>A p.G364E | Missense Mutation (SNP) | VAF 170/492 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CIT | c.4339G>A p.E1447K | Missense Mutation (SNP) | VAF 91/391 reads (23%) | SIFT tolerated (0.12); PolyPhen benign (0.437); called by muse, mutect2, varscan2
- CIT | c.3172G>T p.E1058* | Nonsense Mutation (SNP) | VAF 112/445 reads (25%) | called by muse, mutect2, varscan2
- CLCNKB | c.2033C>T p.S678F | Missense Mutation (SNP) | VAF 64/353 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); called by muse, mutect2
- COL4A4 | c.3974G>A p.G1325E | Missense Mutation (SNP) | VAF 143/278 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by mutect2, varscan2
- CTAGE15 | c.828G>A p.M276I | Missense Mutation (SNP) | VAF 75/192 reads (39%) | SIFT deleterious (0.05); PolyPhen benign (0.059); called by mutect2, varscan2
- CYP2E1 | c.1240T>G p.F414V | Missense Mutation (SNP) | VAF 23/364 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.884); called by muse, mutect2
- DCAF8 | c.721C>T p.Q241* | Nonsense Mutation (SNP) | VAF 229/674 reads (34%) | called by muse, mutect2, varscan2
- DEPDC4 | c.572T>A p.I191N | Missense Mutation (SNP) | VAF 71/278 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.674); called by muse, mutect2, varscan2
- DNAH6 | c.8727G>A p.Q2909= | Splice Region (SNP) | VAF 39/270 reads (14%) | called by muse, mutect2, varscan2
- DNAH7 | c.467C>T p.A156V | Missense Mutation (SNP) | VAF 54/370 reads (15%) | SIFT tolerated (0.27); PolyPhen benign (0.001); called by muse, varscan2
- DRC7 | c.2077G>A p.E693K | Missense Mutation (SNP) | VAF 74/351 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.186); called by muse, mutect2, varscan2
- ELP3 | c.299C>T p.P100L | Missense Mutation (SNP) | VAF 146/486 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- ERVV-2 | c.665C>A p.P222H | Missense Mutation (SNP) | VAF 171/644 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- EVPL | c.3133G>A p.E1045K | Missense Mutation (SNP) | VAF 278/670 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.368); called by muse, mutect2, varscan2
- EXPH5 | c.1804G>A p.D602N | Missense Mutation (SNP) | VAF 150/387 reads (39%) | SIFT tolerated (0.29); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- F13B | c.1410G>A p.W470* | Nonsense Mutation (SNP) | VAF 93/279 reads (33%) | called by muse, mutect2, varscan2
- FAF1 | c.1918C>T p.P640S | Missense Mutation (SNP) | VAF 68/376 reads (18%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.752); called by muse, mutect2, varscan2
- FIP1L1 | c.1286-1G>C p.X429_splice | Splice Site (SNP) | VAF 38/228 reads (17%) | called by muse, varscan2
- FLG | c.4505G>A p.G1502E | Missense Mutation (SNP) | VAF 152/587 reads (26%) | SIFT tolerated (0.65); PolyPhen benign (0.062); called by muse, varscan2
- FOXE1 | c.409T>C p.F137L | Missense Mutation (SNP) | VAF 139/461 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- GCNT3 | c.430G>A p.E144K | Missense Mutation (SNP) | VAF 97/392 reads (25%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- GKN3P | c.529G>A p.E177K | Missense Mutation (SNP) | VAF 69/381 reads (18%) | SIFT tolerated (0.16); PolyPhen benign (0.369); called by muse, mutect2, varscan2
- GLRA4 | c.1210C>T p.L404F | Missense Mutation (SNP) | VAF 206/296 reads (70%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0.151); called by muse, mutect2, varscan2
- GON4L | c.1220C>T p.S407F | Missense Mutation (SNP) | VAF 139/471 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- GPAM | c.1535T>G p.M512R | Missense Mutation (SNP) | VAF 163/324 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); called by muse, mutect2, varscan2
- GPATCH4 | c.125T>G p.I42S | Missense Mutation (SNP) | VAF 149/405 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GPR107 | c.670T>A p.Y224N | Missense Mutation (SNP) | VAF 43/277 reads (16%) | SIFT tolerated (0.47); PolyPhen possibly damaging (0.456); called by muse, mutect2, varscan2
- GRIN2D | c.272T>C p.L91P | Missense Mutation (SNP) | VAF 120/462 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.829); called by muse, mutect2, varscan2
- HECW1 | c.1796G>A p.G599E | Missense Mutation (SNP) | VAF 250/782 reads (32%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- HEG1 | c.107C>T p.S36F | Missense Mutation (SNP) | VAF 224/517 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- HFM1 | c.2405G>A p.G802E | Missense Mutation (SNP) | VAF 42/187 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- HMCN1 | c.12010C>T p.P4004S | Missense Mutation (SNP) | VAF 147/511 reads (29%) | SIFT tolerated (0.19); PolyPhen benign (0.095); called by muse, mutect2, varscan2
- HNF1B | c.1273C>T p.H425Y | Missense Mutation (SNP) | VAF 166/450 reads (37%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- HYDIN | c.2696C>T p.A899V | Missense Mutation (SNP) | VAF 155/384 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- HYDIN | c.849G>C p.K283N | Missense Mutation (SNP) | VAF 13/190 reads (7%) | SIFT tolerated (0.11); PolyPhen benign (0.078); called by muse, mutect2
- IGHG1 | c.405G>A p.M135I | Missense Mutation (SNP) | VAF 136/518 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.19); called by muse, mutect2, varscan2
- ILDR2 | c.766C>T p.P256S | Missense Mutation (SNP) | VAF 228/616 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- INTS6 | c.2650A>G p.I884V | Missense Mutation (SNP) | VAF 94/289 reads (33%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- ITGB1 | c.773T>C p.V258A | Missense Mutation (SNP) | VAF 112/238 reads (47%) | SIFT tolerated (0.59); PolyPhen benign (0.136); called by muse, mutect2, varscan2
- IVL | c.597G>T p.Q199H | Missense Mutation (SNP) | VAF 82/688 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); called by muse, varscan2
- KLRF1 | c.680G>A p.W227* | Nonsense Mutation (SNP) | VAF 61/242 reads (25%) | called by muse, mutect2, varscan2
- KRTAP4-7 | c.200C>T p.P67L | Missense Mutation (SNP) | VAF 258/814 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.327); called by muse, varscan2
- LAMA2 | c.184G>A p.G62R | Missense Mutation (SNP) | VAF 144/378 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); called by muse, mutect2, varscan2
- LINC00514 | c.1339G>A p.A447T | Missense Mutation (SNP) | VAF 154/579 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0.396); called by muse, mutect2, varscan2
- MALRD1 | c.5087A>C p.K1696T | Missense Mutation (SNP) | VAF 47/235 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.175); called by muse, mutect2, varscan2
- MAP2K3 | c.56C>T p.S19F | Missense Mutation (SNP) | VAF 64/506 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.006); called by muse, mutect2
- MARCOL | c.317G>A p.G106E | Missense Mutation (SNP) | VAF 139/242 reads (57%) | SIFT tolerated (0.18); PolyPhen benign (0.097); called by muse, mutect2, varscan2
- MGAM2 | c.412C>T p.H138Y | Missense Mutation (SNP) | VAF 226/1203 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- MGAM2 | c.592G>T p.G198W | Missense Mutation (SNP) | VAF 739/1175 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MIDEAS | c.1861C>T p.P621S | Missense Mutation (SNP) | VAF 88/521 reads (17%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MINPP1 | c.650G>A p.G217E | Missense Mutation (SNP) | VAF 14/235 reads (6%) | SIFT tolerated (0.18); PolyPhen benign (0.015); called by muse, mutect2
- MPDZ | c.2632C>T p.P878S | Missense Mutation (SNP) | VAF 206/338 reads (61%) | SIFT tolerated (0.13); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MYH4 | c.1618G>T p.E540* | Nonsense Mutation (SNP) | VAF 30/420 reads (7%) | called by muse, mutect2
- MYL10 | c.493G>T p.V165L | Missense Mutation (SNP) | VAF 354/676 reads (52%) | SIFT tolerated (0.24); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- NCDN | c.2003T>A p.L668H | Missense Mutation (SNP) | VAF 293/644 reads (45%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.737); called by muse, mutect2, varscan2
- NETO1 | c.469+1G>A p.X157_splice | Splice Site (SNP) | VAF 22/172 reads (13%) | called by muse, mutect2, varscan2
- NETO1 | c.469G>A p.D157N | Missense Mutation (SNP) | VAF 22/177 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.937); called by muse, mutect2, varscan2
- OR10G2 | c.415G>A p.V139M | Missense Mutation (SNP) | VAF 50/494 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- OR2H2 | c.167C>T p.P56L | Missense Mutation (SNP) | VAF 518/938 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.851); called by muse, mutect2, varscan2
- OR4Q2 | c.525G>A p.V175= | Splice Region (SNP) | VAF 137/389 reads (35%) | called by muse, mutect2, varscan2
- OR51D1 | c.808G>A p.G270R | Missense Mutation (SNP) | VAF 222/511 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OR8U1 | c.728C>T p.S243F | Missense Mutation (SNP) | VAF 75/494 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by muse, varscan2
- PDGFD | c.413C>T p.P138L | Missense Mutation (SNP) | VAF 64/420 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- PRDM14 | c.1138C>T p.L380F | Missense Mutation (SNP) | VAF 219/669 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- PREX2 | c.946G>C p.D316H | Missense Mutation (SNP) | VAF 65/328 reads (20%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PREX2 | c.3548G>T p.R1183M | Missense Mutation (SNP) | VAF 123/623 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); called by muse, mutect2, varscan2
- RABGAP1 | c.1795-1G>T p.X599_splice | Splice Site (SNP) | VAF 119/211 reads (56%) | called by muse, mutect2, varscan2
- RFPL4A | c.661G>A p.D221N | Missense Mutation (SNP) | VAF 121/1526 reads (8%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); called by muse, mutect2
- RFPL4AL1 | c.661G>A p.D221N | Missense Mutation (SNP) | VAF 29/257 reads (11%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- RNF103 | c.1334A>G p.D445G | Missense Mutation (SNP) | VAF 138/482 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.174); called by muse, mutect2, varscan2
- SATB1 | c.2063C>T p.T688I | Missense Mutation (SNP) | VAF 186/541 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, varscan2
- SBF2 | c.251C>T p.T84I | Missense Mutation (SNP) | VAF 48/306 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- SCAF1 | c.2176_2178delinsTC p.P726Sfs*12 | Frame Shift Del (DEL) | VAF 232/896 reads (26%) | called by pindel, varscan2*
- SCN10A | c.3559G>A p.E1187K | Missense Mutation (SNP) | VAF 153/378 reads (40%) | SIFT tolerated (0.05); PolyPhen benign (0.169); called by muse, mutect2, varscan2
- SERPINB11 | c.323G>A p.R108K | Missense Mutation (SNP) | VAF 59/342 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- SI | c.3643C>T p.H1215Y | Missense Mutation (SNP) | VAF 67/224 reads (30%) | SIFT tolerated (0.13); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- SLC15A4 | c.1073C>G p.T358R | Missense Mutation (SNP) | VAF 63/297 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.381); called by muse, mutect2, varscan2
- SLC17A2 | c.403T>C p.F135L | Missense Mutation (SNP) | VAF 329/550 reads (60%) | SIFT tolerated (0.54); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- STON2 | c.392C>T p.P131L | Missense Mutation (SNP) | VAF 108/317 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.381); called by muse, mutect2, varscan2
- STXBP4 | c.332A>T p.D111V | Missense Mutation (SNP) | VAF 65/257 reads (25%) | SIFT tolerated (0.5); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SUGT1 | c.844C>T p.P282S (on ENST00000343788 / NM_001130912.3; = p.P250S on NM_006704.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 78/272 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- SUPV3L1 | c.1511C>T p.P504L | Missense Mutation (SNP) | VAF 86/169 reads (51%) | SIFT deleterious (0.03); PolyPhen benign (0.387); called by muse, mutect2, varscan2
- SYT2 | c.109G>A p.G37R | Missense Mutation (SNP) | VAF 182/659 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0); called by muse, mutect2
- TBC1D31 | c.833T>C p.V278A | Missense Mutation (SNP) | VAF 103/259 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TENM2 | c.7205A>G p.N2402S (on ENST00000518659 / NM_001122679.2; = p.N2163S on NM_001080428.3) | Missense Mutation (SNP) | VAF 203/362 reads (56%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.816); called by muse, mutect2, varscan2
- TRAPPC3L | c.304G>A p.E102K | Missense Mutation (SNP) | VAF 60/417 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.301); called by muse, mutect2, varscan2
- TRAV8-1 | c.122G>A p.G41E | Missense Mutation (SNP) | VAF 127/404 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- TRIM66 | c.2275C>T p.P759S | Missense Mutation (SNP) | VAF 46/278 reads (17%) | SIFT tolerated (0.29); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TRPM2 | c.4444A>T p.I1482F | Missense Mutation (SNP) | VAF 300/683 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.216); called by muse, mutect2, varscan2
- TTC9 | c.187C>T p.Q63* | Nonsense Mutation (SNP) | VAF 153/512 reads (30%) | called by muse, mutect2, varscan2
- TTLL7 | c.1445C>T p.S482L | Missense Mutation (SNP) | VAF 70/368 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.293); called by muse, mutect2, varscan2
- TTN | c.19867G>A p.A6623T (on ENST00000591111; = p.A5696T on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 52/435 reads (12%) | PolyPhen benign (0.301); called by muse, mutect2, varscan2
- TTN | c.2677G>A p.E893K (on ENST00000591111; = p.E847K on NM_003319.4) | Missense Mutation (SNP) | VAF 278/559 reads (50%) | PolyPhen benign (0.003); called by muse, mutect2, varscan2
- WDR90 | c.1125C>T p.A375= | Splice Region (SNP) | VAF 116/489 reads (24%) | called by muse, mutect2, varscan2
- XPO1 | c.1819G>T p.V607L | Missense Mutation (SNP) | VAF 72/526 reads (14%) | SIFT tolerated (0.35); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZBTB21 | c.1459C>T p.Q487* | Nonsense Mutation (SNP) | VAF 246/578 reads (43%) | called by muse, mutect2, varscan2
- ZNF133 | c.167G>A p.G56E | Missense Mutation (SNP) | VAF 82/530 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- ZNF208 | c.1737A>C p.K579N | Missense Mutation (SNP) | VAF 16/315 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); called by muse, mutect2
- ZNF536 | c.3101C>T p.T1034I | Missense Mutation (SNP) | VAF 142/524 reads (27%) | SIFT tolerated (0.22); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF567 | c.713C>G p.S238C (on ENST00000536254 / NM_001322913.1; = p.S207C on NM_152603.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 16/444 reads (4%) | SIFT tolerated (0.22); PolyPhen benign (0.001); called by muse, mutect2
- ZNF735 | c.20C>T p.P7L | Missense Mutation (SNP) | VAF 201/740 reads (27%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- ABCA13 | c.12078G>A p.T4026= | Silent (SNP) | VAF 169/548 reads (31%) | catalogued as rs749688838, COSV71282976; called by muse, mutect2, varscan2
- ACAN | c.1215C>T p.F405= | Silent (SNP) | VAF 284/677 reads (42%) | catalogued as rs745961803, COSV104419181; called by muse, mutect2, varscan2
- ADAM29 | c.1344C>T p.F448= | Silent (SNP) | VAF 278/540 reads (51%) | catalogued as rs768870601, COSV63660502; called by muse, mutect2, varscan2
- AKNAD1 | c.1653G>A p.L551= | Silent (SNP) | VAF 44/297 reads (15%) | called by muse, mutect2, varscan2
- AKR1C1 | c.690G>A p.P230= | Silent (SNP) | VAF 137/283 reads (48%) | catalogued as rs782677809; called by muse, mutect2, varscan2
- ANK3 | c.10941G>T p.G3647= | Silent (SNP) | VAF 146/339 reads (43%) | catalogued as COSV55043309; called by muse, mutect2, varscan2
- ANKEF1 | c.2256C>T p.F752= | Silent (SNP) | VAF 285/711 reads (40%) | catalogued as rs776549053, COSV65692232, COSV65692775; called by muse, mutect2, varscan2
- ANKRD30A | c.1911G>A p.G637= (on ENST00000611781; = p.G581= on NM_052997.2) | Silent (SNP) | VAF 97/178 reads (54%) | catalogued as COSV64615949; called by muse, mutect2, varscan2
- AP002495.1 | c.111G>A p.K37= | Silent (SNP) | VAF 135/333 reads (41%) | called by muse, mutect2, varscan2
- ARHGEF17 | c.6177C>T p.L2059= | Silent (SNP) | VAF 67/359 reads (19%) | catalogued as COSV55239469; called by muse, mutect2, varscan2
- ARHGEF37 | c.147C>T p.L49= | Silent (SNP) | VAF 187/322 reads (58%) | called by muse, mutect2, varscan2
- AUTS2 | c.2130T>C p.T710= | Silent (SNP) | VAF 106/548 reads (19%) | called by muse, mutect2, varscan2
- BPTF | c.2247T>C p.G749= | Silent (SNP) | VAF 168/366 reads (46%) | catalogued as rs756652990; called by muse, mutect2, varscan2
- CACNA1G | c.1383G>A p.R461= | Silent (SNP) | VAF 167/498 reads (34%) | called by muse, mutect2, varscan2
- CADPS | c.120G>A p.E40= | Silent (SNP) | VAF 156/391 reads (40%) | called by muse, mutect2, varscan2
- CARMIL3 | c.522G>A p.E174= | Silent (SNP) | VAF 94/386 reads (24%) | catalogued as rs760945060; called by muse, mutect2, varscan2
- CCDC185 | c.876G>A p.Q292= | Silent (SNP) | VAF 65/704 reads (9%) | called by muse, mutect2
- CCL24 | c.66C>T p.I22= | Silent (SNP) | VAF 107/448 reads (24%) | called by muse, mutect2, varscan2
- CCNB3 | c.1257C>A p.S419= | Silent (SNP) | VAF 156/346 reads (45%) | called by mutect2, varscan2
- CDSN | c.1029C>T p.P343= | Silent (SNP) | VAF 239/850 reads (28%) | called by muse, mutect2, varscan2
- CFHR5 | c.315G>A p.L105= | Silent (SNP) | VAF 105/387 reads (27%) | catalogued as COSV56829206; called by muse, mutect2, varscan2
- CLTC | c.564G>A p.R188= | Silent (SNP) | VAF 235/514 reads (46%) | called by muse, mutect2, varscan2
- CNTNAP5 | c.618C>T p.S206= | Silent (SNP) | VAF 83/501 reads (17%) | catalogued as rs367708864; called by muse, mutect2, varscan2
- CPNE7 | c.1549C>T p.L517= | Silent (SNP) | VAF 68/238 reads (29%) | catalogued as rs1156438873; called by muse, mutect2, varscan2
- CRB1 | c.1707C>T p.F569= | Silent (SNP) | VAF 141/506 reads (28%) | catalogued as rs201885772, COSV66329457; called by muse, mutect2, varscan2
- CRYBG3 | c.5514C>T p.S1838= | Silent (SNP) | VAF 111/400 reads (28%) | called by muse, mutect2, varscan2
- CSF1 | c.972C>T p.S324= | Silent (SNP) | VAF 243/526 reads (46%) | called by muse, mutect2, varscan2
- CSMD3 | c.9126T>C p.S3042= (on ENST00000297405 / NM_001363185.1; = p.S2873= on NM_052900.3) | Silent (SNP) | VAF 178/515 reads (35%) | catalogued as COSV99824786; called by muse, mutect2, varscan2
- CYP4B1 | c.840G>A p.R280= | Silent (SNP) | VAF 151/366 reads (41%) | called by muse, mutect2, varscan2
- DHCR7 | c.735C>T p.I245= | Silent (SNP) | VAF 205/490 reads (42%) | catalogued as rs12800, CD982593; ClinVar: conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- DNAH9 | c.9150C>A p.L3050= | Silent (SNP) | VAF 74/430 reads (17%) | catalogued as COSV52357786; called by muse, mutect2, varscan2
- EVPL | c.3132G>A p.G1044= | Silent (SNP) | VAF 284/672 reads (42%) | catalogued as COSV56909566; called by muse, mutect2, varscan2
- FAM118B | c.282C>T p.L94= | Silent (SNP) | VAF 207/438 reads (47%) | called by muse, mutect2, varscan2
- FAM234B | c.924C>T p.I308= | Silent (SNP) | VAF 145/562 reads (26%) | catalogued as rs770000113, COSV52197980; called by muse, mutect2, varscan2
- FGF13 | c.54G>A p.L18= | Silent (SNP) | VAF 126/171 reads (74%) | called by muse, mutect2, varscan2
- GRAMD1B | c.927G>A p.L309= | Silent (SNP) | VAF 116/326 reads (36%) | catalogued as rs760520842; called by muse, mutect2, varscan2
- GRM6 | c.2478G>A p.L826= | Silent (SNP) | VAF 168/310 reads (54%) | called by muse, mutect2, varscan2
- HECTD4 | c.9117C>T p.L3039= | Silent (SNP) | VAF 128/365 reads (35%) | catalogued as rs577558956, COSV66396934; called by muse, mutect2, varscan2
- HELB | c.819T>C p.S273= | Silent (SNP) | VAF 130/484 reads (27%) | called by muse, mutect2, varscan2
- HMGB4 | c.213C>T p.Y71= | Silent (SNP) | VAF 215/525 reads (41%) | called by muse, mutect2, varscan2
- HYDIN | c.7704C>T p.F2568= | Silent (SNP) | VAF 329/666 reads (49%) | catalogued as COSV59259638; called by muse, mutect2, varscan2
- HYDIN | c.2445G>A p.G815= | Silent (SNP) | VAF 93/283 reads (33%) | called by muse, mutect2, varscan2
- ILDR2 | c.765C>T p.G255= | Silent (SNP) | VAF 209/574 reads (36%) | catalogued as rs1032855943; called by muse, varscan2
- INSRR | c.2547C>T p.Y849= | Silent (SNP) | VAF 75/475 reads (16%) | catalogued as rs1436248902, COSV63875867; called by muse, mutect2, varscan2
- KANK4 | c.1818C>T p.S606= | Silent (SNP) | VAF 119/509 reads (23%) | catalogued as rs1311473515; called by muse, varscan2
- KCNG2 | c.258C>T p.R86= | Silent (SNP) | VAF 198/576 reads (34%) | catalogued as COSV100301975; called by muse, mutect2, varscan2
- LIMK2 | c.1816C>T p.L606= | Silent (SNP) | VAF 208/528 reads (39%) | called by muse, mutect2, varscan2
- LOXL2 | c.930C>T p.D310= | Silent (SNP) | VAF 183/545 reads (34%) | catalogued as rs747695442, COSV66690893; called by muse, mutect2, varscan2
- LPAR5 | c.927C>T p.R309= | Silent (SNP) | VAF 135/560 reads (24%) | called by muse, mutect2, varscan2
- LRRIQ1 | c.4800C>T p.P1600= | Silent (SNP) | VAF 65/314 reads (21%) | called by muse, mutect2, varscan2
- MAGEA11 | c.225G>A p.R75= | Silent (SNP) | VAF 196/266 reads (74%) | catalogued as rs1358330855; called by muse, mutect2, varscan2
- MAGEE1 | c.1776C>T p.F592= | Silent (SNP) | VAF 295/401 reads (74%) | called by muse, mutect2, varscan2
- MECOM | c.219G>A p.T73= (on ENST00000468789 / NM_001105078.4; = p.T261= on NM_004991.4) | Silent (SNP) | VAF 131/493 reads (27%) | catalogued as rs150481592; called by muse, mutect2, varscan2
- METTL2A | c.603G>A p.T201= | Silent (SNP) | VAF 84/402 reads (21%) | catalogued as rs1405216228; called by muse, mutect2, varscan2
- MIEF2 | c.1227C>T p.I409= | Silent (SNP) | VAF 74/502 reads (15%) | catalogued as rs749267118, COSV59902631; called by muse, varscan2
- MMP23B | c.1023G>A p.L341= | Silent (SNP) | VAF 30/238 reads (13%) | called by muse, mutect2, varscan2
- MRGPRX1 | c.675C>T p.F225= | Silent (SNP) | VAF 93/539 reads (17%) | catalogued as COSV100246137; called by muse, mutect2, varscan2
- MRTFB | c.1024C>T p.L342= | Silent (SNP) | VAF 185/741 reads (25%) | catalogued as rs1032062152; called by muse, mutect2, varscan2
- MUC16 | c.16839C>T p.T5613= | Silent (SNP) | VAF 83/417 reads (20%) | catalogued as rs530470201; called by muse, mutect2, varscan2
- MYOM1 | c.93G>A p.R31= | Silent (SNP) | VAF 83/528 reads (16%) | catalogued as rs876657536; ClinVar: likely benign; called by muse, mutect2, varscan2
- NLRP5 | c.2202G>A p.R734= | Silent (SNP) | VAF 228/534 reads (43%) | catalogued as rs760106199, COSV66763366; called by muse, mutect2, varscan2
- NOD1 | c.504C>T p.G168= | Silent (SNP) | VAF 272/680 reads (40%) | called by muse, mutect2
- OR14C36 | c.705C>T p.A235= | Silent (SNP) | VAF 202/367 reads (55%) | catalogued as rs759165430, COSV100507556; called by muse, mutect2, varscan2
- OR2L8 | c.102C>T p.F34= | Silent (SNP) | VAF 136/253 reads (54%) | catalogued as COSV61727333; called by muse, mutect2, varscan2
- OR5D18 | c.561C>T p.S187= | Silent (SNP) | VAF 128/328 reads (39%) | catalogued as rs1347293495, COSV61738654; called by muse, mutect2, varscan2
- OR5W2 | c.162A>G p.Q54= | Silent (SNP) | VAF 151/371 reads (41%) | catalogued as rs776275781; called by muse, mutect2, varscan2
- PCDH19 | c.1086C>T p.A362= | Silent (SNP) | VAF 320/427 reads (75%) | catalogued as COSV55271994; called by muse, mutect2, varscan2
- PGLYRP4 | c.447C>T p.G149= | Silent (SNP) | VAF 144/466 reads (31%) | catalogued as rs868290643; called by muse, mutect2
- PIEZO2 | c.5538C>T p.D1846= | Silent (SNP) | VAF 242/528 reads (46%) | catalogued as rs539810112; ClinVar: likely benign; called by muse, mutect2, varscan2
- PIP5K1C | c.447G>A p.G149= | Silent (SNP) | VAF 39/233 reads (17%) | catalogued as rs1568334078; called by muse, mutect2, varscan2
- PLCG2 | c.2718C>T p.I906= | Silent (SNP) | VAF 195/420 reads (46%) | called by muse, mutect2, varscan2
- PLCH1 | c.3588C>T p.I1196= (on ENST00000340059 / NM_001130960.2; = p.I1188= on NM_014996.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 156/559 reads (28%) | catalogued as COSV58189980; called by muse, mutect2, varscan2
- PLG | c.855G>A p.G285= | Silent (SNP) | VAF 85/423 reads (20%) | catalogued as rs202061577, COSV51987197; called by muse, mutect2, varscan2
- PTPRF | c.3348C>T p.F1116= | Silent (SNP) | VAF 84/478 reads (18%) | catalogued as rs199683329, COSV63443266; called by muse, mutect2, varscan2
- PTPRK | c.2568C>T p.S856= (on ENST00000368215 / NM_001291984.2; = p.S857= on NM_002844.4) | Silent (SNP) | VAF 91/566 reads (16%) | called by muse, mutect2, varscan2
- REXO1 | c.2910C>T p.C970= | Silent (SNP) | VAF 123/344 reads (36%) | called by muse, mutect2, varscan2
- RP1 | c.588C>G p.V196= | Silent (SNP) | VAF 98/513 reads (19%) | called by muse, mutect2, varscan2
- RPL18 | c.76A>C p.R26= | Silent (SNP) | VAF 135/335 reads (40%) | called by muse, mutect2, varscan2
- RSBN1 | c.2058C>T p.F686= | Silent (SNP) | VAF 152/350 reads (43%) | catalogued as COSV54733487; called by muse, mutect2, varscan2
- S1PR2 | c.603C>T p.I201= | Silent (SNP) | VAF 146/346 reads (42%) | called by muse, mutect2, varscan2
- SHCBP1L | c.18G>A p.K6= | Silent (SNP) | VAF 191/485 reads (39%) | called by muse, mutect2, varscan2
- SHISAL1 | c.456C>T p.P152= | Silent (SNP) | VAF 266/616 reads (43%) | catalogued as rs751318053, COSV66988553; called by muse, mutect2, varscan2
- SHROOM3 | c.2325G>A p.G775= | Silent (SNP) | VAF 64/525 reads (12%) | catalogued as COSV99934975; called by muse, mutect2, varscan2
- SHROOM3 | c.3129G>A p.Q1043= | Silent (SNP) | VAF 365/687 reads (53%) | called by muse, mutect2, varscan2
- SLC12A5 | c.2241G>A p.R747= (on ENST00000454036 / NM_001134771.2; = p.R724= on NM_020708.5) | Silent (SNP) | VAF 128/424 reads (30%) | called by muse, mutect2, varscan2
- SLC35F4 | c.951C>T p.V317= (on ENST00000339762 / NM_001352015.2; = p.V281= on NM_001206920.1 and 1 other RefSeq transcript) | Silent (SNP) | VAF 85/275 reads (31%) | called by muse, mutect2, varscan2
- SLC6A20 | c.1287C>T p.P429= | Silent (SNP) | VAF 106/367 reads (29%) | called by muse, mutect2, varscan2
- SMG7 | c.2700C>T p.V900= | Silent (SNP) | VAF 173/527 reads (33%) | catalogued as COSV61633822; called by muse, mutect2, varscan2
- SPESP1 | c.216A>G p.S72= | Silent (SNP) | VAF 181/455 reads (40%) | called by muse, mutect2, varscan2
- SRRM2 | c.3513C>T p.P1171= | Silent (SNP) | VAF 100/532 reads (19%) | catalogued as rs376935717; called by muse, mutect2, varscan2
- STRA6 | c.1075C>T p.L359= | Silent (SNP) | VAF 178/384 reads (46%) | called by muse, mutect2, varscan2
- STXBP4 | c.333C>T p.D111= | Silent (SNP) | VAF 66/262 reads (25%) | called by muse, mutect2, varscan2
- SYNJ2 | c.2583C>T p.I861= | Silent (SNP) | VAF 99/281 reads (35%) | catalogued as rs201337191; called by muse, mutect2, varscan2
- TEKT5 | c.1167G>A p.K389= | Silent (SNP) | VAF 346/733 reads (47%) | catalogued as rs770918984; called by muse, mutect2, varscan2
- TEX13D | c.381C>T p.L127= | Silent (SNP) | VAF 212/299 reads (71%) | catalogued as rs899097362; called by muse, mutect2, varscan2
- TEX15 | c.525G>A p.E175= (on ENST00000256246; = p.E558= on NM_001350162.2) | Silent (SNP) | VAF 214/529 reads (40%) | catalogued as rs1344222138; called by muse, mutect2, varscan2
- THSD7B | c.2724G>A p.Q908= | Silent (SNP) | VAF 49/353 reads (14%) | catalogued as rs1043842396; called by muse, mutect2, varscan2
- TLR8 | c.1242C>T p.F414= (on ENST00000218032 / NM_138636.5; = p.F432= on NM_016610.4) | Silent (SNP) | VAF 133/174 reads (76%) | called by muse, mutect2, varscan2
- TMEM185B | c.999C>T p.S333= | Silent (SNP) | VAF 252/487 reads (52%) | called by muse, mutect2, varscan2
- TRIP11 | c.1302G>T p.L434= | Silent (SNP) | VAF 76/260 reads (29%) | catalogued as COSV99971106; called by muse, mutect2, varscan2
- TTN | c.59649G>A p.L19883= (on ENST00000591111; = p.L12459= on NM_003319.4) | Silent (SNP) | VAF 293/550 reads (53%) | called by muse, mutect2, varscan2
- TTN | c.22476G>A p.G7492= (on ENST00000591111; = p.G6565= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 84/530 reads (16%) | catalogued as COSV59905401; called by muse, mutect2, varscan2
- XKR6 | c.990C>T p.S330= | Silent (SNP) | VAF 150/465 reads (32%) | catalogued as rs748570952; called by muse, mutect2, varscan2
- ZCWPW1 | c.1140C>T p.F380= | Silent (SNP) | VAF 181/609 reads (30%) | called by muse, mutect2, varscan2
- ZNF268 | c.2535C>T p.F845= | Silent (SNP) | VAF 98/764 reads (13%) | called by muse, mutect2, varscan2
- ZNF358 | c.1224C>T p.A408= | Silent (SNP) | VAF 22/98 reads (22%) | catalogued as rs778571532; called by muse, mutect2, varscan2
- ZNF709 | c.546C>T p.S182= | Silent (SNP) | VAF 77/389 reads (20%) | called by muse, mutect2, varscan2
- ZNF737 | c.1254C>T p.I418= | Silent (SNP) | VAF 131/419 reads (31%) | catalogued as rs782328523, COSV101417734; called by muse, mutect2, varscan2
- ZSCAN20 | c.2277C>T p.I759= | Silent (SNP) | VAF 102/572 reads (18%) | catalogued as COSV100792699; called by muse, mutect2, varscan2
- C8orf34 | c.1106-14725G>A | Intron (SNP) | VAF 184/609 reads (30%) | called by muse, mutect2, varscan2
- DMXL1 | c.7863+3454C>T | Intron (SNP) | VAF 111/226 reads (49%) | called by muse, mutect2, varscan2
- KCNQ1 | c.1394-5402C>T | Intron (SNP) | VAF 63/330 reads (19%) | called by muse, mutect2, varscan2
- PCLO | c.13300+145G>A | Intron (SNP) | VAF 116/520 reads (22%) | catalogued as COSV100433286; called by muse, mutect2, varscan2
- SYTL2 | c.1459+3056G>A | Intron (SNP) | VAF 60/311 reads (19%) | called by muse, mutect2, varscan2
- TPM1 | c.240+28C>T | Intron (SNP) | VAF 152/660 reads (23%) | catalogued as rs1161293287; called by muse, mutect2, varscan2
- TRIOBP | c.5322+5248G>A | Intron (SNP) | VAF 268/604 reads (44%) | called by muse, varscan2
- TRIOBP | c.5322+5249G>A | Intron (SNP) | VAF 266/604 reads (44%) | catalogued as rs759360046; called by muse, varscan2
